Somatic mutation profile of tumor specimen BA2354D (aliquot aq-BA2354D) from BEATAML1.0 case 2050, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 37.9 years (13,846 days).
Specimen BA2354D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c47e2518-8b0a-4c62-9bb9-68e2839cd393.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2434D (Solid Tissue Normal), aliquot aq-BA2434D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4921f4ba-961c-4a87-ac29-cec27f359788

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.1718C>A p.P573Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229258; called by muse, mutect2
- AGO3 | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV55797397; called by muse, mutect2
- ALYREF | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58668867; called by muse, mutect2
- DHX15 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028061, COSV61028114, COSV61028271; called by muse, mutect2
- SCN5A | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs137854609, CM014388, CM100685, COSV61119231; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM121B | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); catalogued as rs1418333713, COSV100510965; called by muse, mutect2
- MORC4 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STIM2 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSPYL2 | c.1475C>A p.T492N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ZNF646 | c.936C>A p.H312Q | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CRTAP | c.291C>A p.A97= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MARCHF9 | c.300C>T p.S100= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, varscan2
- STK25 | c.1236G>T p.V412= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TDRD6 | c.963C>A p.G321= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- ABR | c.1962-337G>T | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ARHGAP27P2 | n.206C>A | RNA (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
